Surgical pathology report (de-identified scan), TCGA case TCGA-73-4659, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4659-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. LEVEL 7 SUBCARINAL
B. 4R RIGHT DISTAL PARATRACHEAL
C. 4R RIGHT DISTAL PARATRACHEAL
D. SUPERIOR SEGMENT RIGHT UPPER LOBE
E. 6TH RIB
F. RIGHT LUNG
G. 10R LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA & B: Lymph nodes 4R and 7, biopsy:

- Negative for carcinoma by

FSC: Lymph node 4R, biopsy:

- Positive for adenocarcinoma

P.M.

FSF: Right lung, pneumonectomy:

- Bronchial margin negative for invasive carcinoma. Moderate to severe squamous
bronchial dysplasia by

GROSS DESCRIPTION:

A. LEVEL 7 SUBCARINAL LYMPH NODE:

Received fresh for frozen section is a lymph node measuring 0.7 cm. The specimen is submitted in toto for frozen section and resubmitted in cassette A1.

[page 2 of 4]
B. 4R RIGHT DISTAL PARATRACHEAL:

Received fresh for frozen section is a lymph node measuring 0.7 cm. The specimen is submitted in toto for frozen section and resubmitted in cassette B1.

C. 4R RIGHT DISTAL PARATRACHEAL:

Received fresh is a lymph node measuring 1.5 x 1.0 x 0.5 cm. The specimen is serially sectioned and a touch preparation is made. The specimen is submitted in toto for frozen section and resubmitted in cassette C1.

D. SUPERIOR SEGMENT RIGHT UPPER LOBE:

Received in formalin are multiple pieces of lung which are 1.0 x 0.6 x 0.2 cm. in aggregate. The specimen is submitted in toto in cassette D1.

E. 6TH RIB:

Received in formalin is a segment of rib measuring 1.9 x 1.8 x 1.0 cm. The specimen is grossly unremarkable, and no sections are submitted.

F. RIGHT LUNG:

Received fresh is a right lung with a 9.0 x 5.0 x 2.0 cm right middle lobe, and a 7.5 x 7.0 x 3.0 cm right lower lobe, and a 14.5 x 8.5 x 6.5 cm right upper lobe. There is a 9.0 x 6.0 x 3.0 cm. tumor extending from the upper lobe into the lower lobe. The tumor is peripherally located, is 1.5 cm. from the bronchial margin, 0.1 cm from superior pleural surface, and 0.1 cm away from lateral pleural surface. A second 1.5 cm. in diameter nodule is present in the center of the lower lobe. The bronchial margin is shaved and submitted for frozen section and resubmitted in cassette F1.

Cassette F2: tumor in the superior aspect

Cassette F3: tumor in the lateral aspect

Cassette F4: tumor in the posterior aspect

Cassette F5: tumor in the medial aspect

Cassette F6-F8: representative sections from tumor

Cassette F9: tumor from the lower lobe

Cassette F10: separate tumor nodule in the center of lower lobe

Cassette F11: bronchus and adjacent lymph node from the lower lobe

Cassette F12: bronchus and adjacent lymph node from the upper lobe

Cassette F13: multiple lymph nodes near the bronchus near the upper lobe

Cassette F14: multiple lymph nodes near the bronchus around the lower lobe

Cassette F15: representative sections from the bronchus

Cassette F16: uninvolved upper lobe

Cassette F17: uninvolved middle lobe

Cassette F18: uninvolved lower lobe

[page 3 of 4]
G. 10R LYMPH NODE:

Received in formalin is a piece of yellow-tan lymph node measuring 1.5 x 1.2 x 0.5 cm. The specimen is submitted in toto in cassette G1.

DIAGNOSIS:

A. LYMPH NODE, SUBCARINAL-LEVEL 7, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

B. LYMPH NODE, RIGHT DISTAL PARATRACHEAL-4R, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).

C. LYMPH NODE, RIGHT DISTAL PARATRACHEAL-4R, EXCISION:

- METASTATIC CARCINOMA TO ONE LYMPH NODE (1/1).

D. LUNG, RIGHT UPPER LOBE SUPERIOR SEGMENT, BIOPSY:

- POSITIVE FOR ADENOCARCINOMA, SEE PART F BELOW.

E. BONE, 6TH RIB, SEGMENTAL RESECTION:

- NO GROSS HISTOPATHOLOGICAL ABNORMALITIES (GROSS ONLY).

F. LUNG, RIGHT, PNEUMONECTOMY:

- ADENOCARCINOMA, MODERATELY DIFFERENTIATED WITH FOCAL POORLY DIFFERENTIATED AREAS, SEE COMMENT AND SEE TEMPLATE.
- 9.0 CM IN GREATEST DIMENSION.
- SPANNING BOTH THE UPPER AND LOWER LOBES.
- THE PLEURAL SURFACE IS NEGATIVE FOR TUMOR.
- THE BRONCHIAL MARGIN IS NEGATIVE FOR INVASIVE CARCINOMA.
- THE RESPIRATORY MUCOSA AT THE BRONCHIAL MARGIN FOCALLY CONTAINS MILD TO MODERATE DYSPLASIA.
- 1.5 CM FROM THE BRONCHIAL MARGIN.
- ANGIOLYMPHATIC INVASION IS PRESENT.
- ADENOCARCINOMA IN SITU INVOLVES THE RESPIRATORY MUCOSA WITHIN THE TUMOR MASS.
- METASTATIC ADENOCARCINOMA TO TWO OF TWELVE PERIBRONCHIAL LYMPH NODES (2/12).
- PERIBRONCHIAL LYMPH NODES CONTAINING CALCIFIED AND HYALINIZED GRANULOMAS.
- THE NON-NEOPLASTIC LUNG CONTAINS EMPHYSEMATOUS CHANGES.

G. LYMPH NODE, 10R, EXCISION:

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
-

[page 4 of 4]
COMMENT: The adenocarcinoma is predominantly moderately differentiated, however, it contains areas where the tumor forms solid sheets of cells rather than forming glands in these areas contain some signet ring cells. These areas are poorly differentiated. Some of these signet ring cells are present in the metastasis in part C. Two tumor nodules were identified grossly, the smaller 1.5 cm nodule was an old hyalinized granuloma.

LUNG NEOPLASM TEMPLATE

Surgical procedure:	Pneumonectomy
Tumor location:	Upper and lower lobes, central
Tumor size:	9.0 cm
Tumor type:	Adenocarcinoma
Histologic grade:	Moderate with poorly differentiated areas
Angiolymphatic invasion:	Present
Bronchial margin:	Negative
Distance from bronchial margin:	1.5 cm
Visceral pleural involvement:	Absent
Satellite tumor(s):	Absent
Lymph node involvement:	N1: Positive (2/13)
	N2: Positive (1/3)
	N3: NA
Non-neoplastic lung:	Emphysematous changes
Pathologic stage:	pT2 N2 MX

Source: NCI Genomic Data Commons file 8617a3d9-6e66-481d-95a4-c6e89cad5b98 (TCGA-73-4659.A6F30521-A0D2-4871-8B9F-A338F15CE8E8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).